Gene-level copy-number profile of tumor specimen ALCH-B1T1-TTP1-A from ALCHEMIST case ALCH-B1T1, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 68.3 years (24,944 days).
Specimen ALCH-B1T1-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 4b3813da-37de-439e-bf1b-ecf4533c39e9.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B1T1-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,232 have no estimate.
https://portal.gdc.cancer.gov/files/9ca258f4-a5e6-40af-9e8e-5cdca35eb3f0

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 69; copy number 1: 20,099; copy number 2: 32,301; copy number 3: 3,320; copy number 4: 1,773; copy number 5: 39; copy number 6: 2; copy number 7: 146; copy number 8: 377; copy number 9: 148; copy number 12: 1; copy number 13: 52; copy number 18: 5; copy number 24: 3; copy number 27: 2; copy number 29: 6; copy number 30: 7; copy number 35: 3; copy number 38: 1; copy number 40: 33; copy number 47: 2; copy number 76: 2.

Homozygous deletions (total copy number 0; autosomes only): 69 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:212,911,003–212,926,336, 3 genes (within-gene range 0–2): AC108066.1, MIR4776-1, MIR4776-2.
- chr3:75,395,188–75,670,185, 20 genes: LSP1P2, AC139453.1, ALG1L6P, FAM86DP, LINC02018, ENPP7P2, SNRPCP10, AC133041.1, RPS3AP15, AC108724.1, OR7E121P, UNC93B3, RPL23AP49, AC108724.2, CLUHP10, MIR1324, AGGF1P3, RARRES2P1, FRG2C, DUX4L26.
- chr4:625,573–670,782, 3 genes (within-gene range 0–1): PDE6B, PDE6B-AS1, AC107464.2.
- chr4:68,537,184–68,670,652, 5 genes (within-gene range 0–1): UGT2B17, AC147055.2, AC147055.4, AC147055.3, UGT2B15.
- chr4:69,280,475–69,423,164, 7 genes (within-gene range 0–1): UGT2B28, AC114786.3, AC114786.2, AC114786.4, UGT2B25P, AC108078.1, UGT2B24P.
- chr7:113,078,331–113,087,778, 1 gene: GPR85.
- chr9:135,702,185–135,795,508, 1 gene: KCNT1.
- chr14:105,597,691–105,601,728, 1 gene (within-gene range 0–2): IGHE.
- chr15:25,180,497–25,218,698, 21 genes (within-gene range 0–1): SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26.
- chr17:19,061,912–19,096,837, 6 genes: SNORD3B-1, SNORD3B-2, AC007952.3, KYNUP2, AC007952.7, AC007952.2.
- chr19:10,350,529–10,380,572, 1 gene: TYK2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 654 genes in 22 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:32,354,350–33,468,091, 16 genes, copy number 8: ZFR, MIR579, AC074134.1, SUB1, LINC02061, NPR3, AC025459.1, AC010343.3, LINC02120, AC034223.1, AC034223.2, AC010343.2, AC010343.1, LINC02160, AC034231.1, TARS1.
- chr5:63,301,523–63,302,056, 1 gene, copy number 6: AC025445.1.
- chr5:69,560,191–69,624,049, 2 genes, copy number 5: GTF2H2C, NAIPP3.
- chr5:166,905,222–168,269,415, 15 genes, copy number 7–8 (within-gene range 2–8): LINC01947, AC091819.2, AC091819.1, TENM2, AC091820.2, AC091820.1, AC008601.1, AC008708.2, AC008708.1, AC008464.1, AC008705.2, AC008705.1, AC011369.1, AC011369.2, CTB-178M22.2.
- chr7:30,516,309–30,595,286, 1 gene, copy number 9 (within-gene range 4–9): GARS1-DT.
- chr7:30,580,533–56,229,782, 418 genes, copy number 8–9 (broad region; genes not listed).
- chr7:87,627,548–87,909,553, 3 genes, copy number 13 (within-gene range 2–13): RUNDC3B, SLC25A40, DBF4.
- chr7:88,270,892–88,756,725, 2 genes, copy number 24–38 (within-gene range 2–47): STEAP4, AC002069.2.
- chr7:88,564,793–88,749,694, 4 genes, copy number 24–47: KPNA2P2, PQLC1P1, EEF1A1P28, AC002127.1.
- chr7:90,383,721–90,513,402, 2 genes, copy number 13 (within-gene range 2–13): CLDN12, AC006153.1.
- chr7:90,469,639–90,513,397, 1 gene, copy number 13 (within-gene range 2–13): AC002456.2.
- chr7:91,638,847–91,643,512, 1 gene, copy number 27: AC000058.1.
- chr7:91,940,862–92,401,383, 11 genes, copy number 13: AKAP9, CYP51A1, AC000120.2, AC000120.3, CYP51A1-AS1, LRRD1, KRIT1, AC000120.1, Y_RNA, MIR1285-1, ANKIB1.
- chr7:92,457,564–92,917,187, 11 genes, copy number 35–40 (within-gene range 2–40): AC007566.1, ERVW-1, PEX1, RBM48, AC005156.1, FAM133B, CDK6, AC000065.2, AC000065.1, RNU6-10P, CDK6-AS1.
- chr7:93,890,913–94,077,157, 8 genes, copy number 13 (within-gene range 2–13): TFPI2-DT, AC002076.1, GNG11, AC006378.1, BET1, BET1-AS1, AC003092.1, AC003092.2.
- chr14:18,333,726–18,419,273, 4 genes, copy number 5: CR383658.1, RNU6-458P, CR383658.2, BNIP3P6.
- chr14:34,515,938–37,579,125, 79 genes, copy number 5–76 (broad region; genes not listed).
- chr14:63,122,888–64,338,112, 27 genes, copy number 13 (within-gene range 2–13): AL137191.1, PARP1P2, RHOJ, AL049871.1, GPHB5, PPP2R5E, AL132992.1, AL136038.3, AL136038.1, GCATP1, WDR89, AL136038.2, HSPE1P2, RNU6-597P, Y_RNA, RNU6-1162P, AL136038.4, U3, SGPP1, EIF2S2P1, RNU7-116P, SYNE2, AL161670.1, RPS28P1, Y_RNA, ESR2, MIR548H1.
- chr17:18,476,737–18,494,945, 1 gene, copy number 12: LGALS9C.
- chr21:14,676,698–16,873,691, 36 genes, copy number 7: AF127936.1, POLR2CP1, GAPDHP16, AF127577.4, LINC02246, RBMX2P1, AF127577.3, NRIP1, AF127577.1, AF127577.2, AF127577.6, AF127577.5, AF246928.1, AJ009632.2, CYCSP42, AJ009632.1, RNU6-1326P, RAD23BP3, USP25, RBPMSLP, MIR99AHG, RNU6-426P, VDAC2P1, RPS26P5, SNORD74B, AP001172.1, AP001172.2, AP000962.3, AP000962.2, MIR99A, MIRLET7C, AP000962.1, MIR125B2, RNU1-98P, AF130359.1, AF212831.1.
- chr21:17,438,821–17,633,199, 9 genes, copy number 8: LINC01549, RPL39P40, RN7SL163P, CXADR, BTF3L4P1, Y_RNA, Y_RNA, BTG3, BTG3-AS1.
- chr22:18,650,023–18,719,341, 2 genes, copy number 6–8: PPP1R26P2, PPP1R26P4.

Autosomal genes at a single copy (total copy number 1): 20,028. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
